Surgical pathology report (de-identified scan), TCGA case TCGA-39-5011, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site MSKCC, specimen TCGA-39-5011-01A (Primary Tumor).

[page 1 of 3]
HOLOGY REPORT

Accession #:

Service:

Date of

Date of

Date of

TCGA-39-5011

Clinical Diagnosis and History:

Right upper lobe lung mass. FNA => right lung NSCLC.

Specimens Submitted:

- 1: SP: Level 7 lymph node (fs) (pjm)
- 2: SP: Level 7 lymph node #2 (fs)
- 3: SP: Level 11 lymph node
- 4: SP: Rt. lower lobe xt. upper lobe lung wedge

DIAGNOSIS:

- 1) LYMPH NODES, LEVEL VII; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 2) LYMPH NODES, LEVEL VII #2; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 3) LYMPH NODES, LEVEL XI; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 4) LUNG, RIGHT LOWER AND UPPER LOBES; LOBECTOMY AND WEDGE RESECTION:
- NON-SMALL CELL CARCINOMA WITH PROMINENT SOLID GROWTH PATTERN, AND FEATURES SUGGESTIVE OF FOCAL SQUAMOUS DIFFERENTIATION, POORLY DIFFERENTIATED, OF RIGHT LOWER LOBE. THE TUMOR GREATEST DIAMETER IS <= 3 CM. NO VASCULAR INVASION IS IDENTIFIED. NO PERINEURAL INVASION IS IDENTIFIED. THE BRONCHIAL MARGIN IS FREE OF TUMOR. THE TUMOR EXTENDS SUBPLEURALLY BUT NOT TO THE PLEURAL SURFACE. THE NON-NEOPLASTIC LUNG SHOWS THE FOLLOWING ABNORMALITIES: EMPHYSEMATOUS CHANGES AND INTERSTITIAL FIBROSIS. THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED): PERIBRONCHIAL: 0/1.

** Report Electronically Signed Out **

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

PATH
REPORT

** Continued on next page **

11

[page 2 of 3]
Gross Description:

1) The specimen is received fresh for frozen section, labeled as "Level 7 lymph node". It consists of two lymph nodes measuring 1 and 2 cm in greatest dimension. The largest lymph node was bisected and submitted entirely in one cassette.

Summary of sections:

FSC - frozen section control

2) The specimen is received fresh for frozen section, labeled as "Level 7 lymph node #2". It consists of two lymph nodes measuring from 0.9 up to 1.5 cm. Submitted entirely in one cassette.

Summary of sections:

FSC - frozen section control

3) The specimen is received in formalin, labeled "Level 11 lymph node". It consists of two pink-red anthracotic lymph nodes measuring from 0.5 up to 0.7 cm in greatest dimension. Submitted entirely in one cassette.

Summary of sections:

LN - lymph nodes

4) The specimen is received fresh, labeled "Right lower lobe and right upper lobe lung wedge". It consists of a lower lobe of lung with adherent wedge shaped fragment of upper lobe weighing 180 grams. The lower lobe measures 19 x 8 x 5 cm. The wedge shaped fragment of upper lobe measures 4.5 x 1 x 1 cm. Noted at area of pleural retraction is an induration measuring 1.5 cm in greatest dimension and is located at the area of adhesion of wedge shaped fragment to the lower lobe. The area of pleural retraction is inked blue. The rest of the pleural surface is inked red and intact. The cut surface for the indurated area reveals a well circumscribed pink-gray subpleural peripheral focally necrotic tumor which measures 2 x 1.5 x 1.5 cm. Grossly, the tumor involves the portion of the lower lobe of the lung and portion of the upper lobe and it comes within 0.5 cm from the stapled surgical margin of the wedge. The rest of the lung parenchyma of the lower lobe and wedge shaped fragment of the upper lobe is pink red and grossly unremarkable. Grossly no

** Continued on next page **

[page 3 of 3]
tumor is present in the airways. The epithelium of the bronchial is tan and smooth. Noted is an anthracotic bronchial lymph node which measures 0.5 cm in greatest dimension. Representative sections are submitted.

Summary of Sections:

BM - bronchial surgical margin
VM - vascular surgical margin
LN - peri-bronchial lymph node
TA - tumor at the site of adhesion of the lower lobe and the wedge shaped fragment of the upper lobe
T - representative sections of the tumor
SM - representative sections of the stapled surgical margin of the wedge
LL - representative sections of the grossly unremarkable lung parenchyma of the lower lobe
UL - representative sections of the wedge

Summary of Sections:

Part	Sect. Site	Blocks	Pieces	All
1	FSC	1	3	Y
2	FSC	1	2	Y
3	LN	1	2	Y
4	BM	1	1	N
	LL	3	3	
	LN	1	1	
	SM	1	M	
	T	1	1	
	TA	2	2	
	UL	1	2	
	VM	1	M	

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]
PERMANENT DIAGNOSIS: SAME.

PATH
REPORT
11

** End of Report **

Source: NCI Genomic Data Commons file 9fc9a068-9948-45f1-a059-6865d3edcb64 (TCGA-39-5011.6D1EE212-F843-4E78-908A-4CFD5F01A0A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).